Somatic mutation profile of tumor specimen ALCH-AE5P-TTP1-A (aliquot ALCH-AE5P-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AE5P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,774 days).
Specimen ALCH-AE5P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfebdb2b-da0a-4b9d-b2de-ace5abf77bc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE5P-NB1-A (Blood Derived Normal), aliquot ALCH-AE5P-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2801aa7-eab3-4a33-afc6-76dea31506bf

The open-access MAF lists 194 somatic variants for this specimen: 116 protein-altering or splice-affecting, 57 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 57, Nonsense Mutation 15, Intron 10, 3'UTR 4, RNA 4, Translation Start Site 2, 5'UTR 2, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 149/644 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/324 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ARID2 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 23/240 reads (10%) | catalogued as COSV57610169; called by muse, mutect2
- ATF3 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1470067982; called by muse, mutect2
- CACNA1H | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771994752, COSV100672633; called by muse, mutect2, varscan2
- CD2BP2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV99977248; called by muse, mutect2
- CEP162 | c.1670T>C p.L557S | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1397176537; called by muse, mutect2
- CNKSR1 | c.1561G>A p.E521K (on ENST00000374253 / NM_001297647.2; = p.E514K on NM_006314.3) | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58792365; called by muse, mutect2
- CSKMT | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV63473504; called by muse, mutect2
- EIF4EBP2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV64667125; called by muse, mutect2
- FBXO24 | c.689C>T p.S230F (on ENST00000241071 / NM_033506.3; = p.S268F on NM_012172.5) | Missense Mutation (SNP) | VAF 27/420 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1201268695, COSV53825754; called by muse, mutect2
- FGD4 | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.716); catalogued as COSV56781973, COSV56782798; called by muse, mutect2
- FOXO6 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0.01); catalogued as COSV65429306; called by muse, mutect2
- FUT9 | c.588G>C p.W196C | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV56156530; called by muse, mutect2
- GAN | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 42/445 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs773971284, COSV73721471; called by muse, mutect2, varscan2
- GPRC6A | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100113903; called by muse, mutect2, varscan2
- GRIK3 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV100902292; called by muse, mutect2
- HERPUD2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV60945553; called by muse, mutect2
- LMTK2 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as COSV52001129; called by muse, mutect2
- MCM3 | c.2372C>G p.S791C (on ENST00000229854 / NM_001366374.2; = p.S781C on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99038443; called by muse, mutect2
- MNDA | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 13/210 reads (6%) | catalogued as COSV100933282, COSV63742049; called by muse, mutect2
- NRDC | c.3566C>G p.S1189C | Missense Mutation (SNP) | VAF 56/730 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61404082; called by muse, mutect2
- OR2W3 | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV99075134; called by muse, mutect2, varscan2
- OR5M11 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1165799172, COSV73141974; called by muse, mutect2
- PASD1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.062); catalogued as COSV64855543; called by muse, mutect2
- PDE4B | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 18/293 reads (6%) | catalogued as COSV58501274; called by muse, mutect2
- PGM2 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV67938732, COSV67939346; called by muse, mutect2
- PHF3 | c.751C>G p.H251D | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV50331159; called by muse, mutect2, varscan2
- PNLIP | c.841T>A p.L281I | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV65040141; called by muse, mutect2, varscan2
- POTEA | c.1376C>G p.S459* (on ENST00000519951 / NM_001005365.2; = p.S413* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 28/290 reads (10%) | catalogued as rs370141349; called by muse, mutect2
- PSG7 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 43/251 reads (17%) | catalogued as COSV68445394; called by muse, mutect2, varscan2
- RILPL1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1354591946; called by muse, mutect2, varscan2
- RUNX1 | c.766C>T p.Q256* (on ENST00000344691 / NM_001001890.3; = p.Q283* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 40/374 reads (11%) | catalogued as COSV55882500; called by muse, mutect2, varscan2
- SAMD9 | c.2935T>C p.C979R | Missense Mutation (SNP) | VAF 48/743 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs370900227; called by muse, mutect2
- SIGLEC1 | c.4805C>T p.A1602V | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs370128295; called by muse, mutect2, varscan2
- STAG1 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV99365266; called by muse, mutect2
- TET1 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65381978; called by muse, mutect2
- THY1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV52455088; called by muse, mutect2
- TTC6 | c.75G>C p.L25F (on ENST00000267368; = p.L1294F on NM_001310135.3) | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as rs367933467; called by muse, mutect2
- TTLL1 | c.1247G>C p.R416T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs753082304; called by muse, mutect2, varscan2
- USP5 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV99979211; called by muse, mutect2
- WNK1 | c.6917C>G p.S2306C (on ENST00000315939 / NM_018979.4; = p.S2058C on NM_014823.3) | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV57273164; called by muse, mutect2
- WT1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV60068623; called by muse, mutect2, varscan2
- ZNF101 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs144162757, COSV58909110; called by muse, mutect2, varscan2
- ZNF354A | c.1180A>G p.S394G | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs1561615112; called by muse, mutect2, varscan2
- ZNF461 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 24/619 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1001376117; called by muse, mutect2
- ZNF518A | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100283572; called by muse, mutect2
- ZNF573 | c.790C>G p.H264D (on ENST00000536220 / NM_001172692.1; = p.H206D on NM_152360.3) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265641; called by muse, mutect2, varscan2
- ADARB2 | c.1622G>T p.W541L | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ANGPTL5 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 55/544 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ANKH | c.706A>T p.K236* | Nonsense Mutation (SNP) | VAF 104/688 reads (15%) | called by muse, varscan2
- ANKRD34C | c.1533G>C p.K511N | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- AP002748.5 | c.735G>C p.K245N | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APIP | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ARHGAP23 | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); called by muse, mutect2
- BSN | c.3670C>G p.L1224V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.031); called by muse, mutect2
- CCNB3 | c.3838A>G p.T1280A | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CFAP206 | c.1130C>G p.T377S | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.054); called by muse, mutect2
- CFAP54 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- DLL1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2
- DNAJC15 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- DNASE1L2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- DPY19L2 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DSCAM | c.1858G>T p.V620F | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- FAM111B | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- FAM193A | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2
- FANCE | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- FLNA | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
- FOXO6 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2
- GALC | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2
- GGCX | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GGNBP2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GSDMB | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HEATR9 | c.1557G>C p.L519F | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- HGH1 | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 42/968 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXD3 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- IGHV1-45 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- ITPK1 | c.462C>T p.F154= | Splice Region (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- KIAA0232 | c.2788C>G p.L930V | Missense Mutation (SNP) | VAF 26/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLF6 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRIT1 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 26/645 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRTAP22-2 | c.45C>A p.C15* | Nonsense Mutation (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- LCOR | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- LRP2 | c.6633G>T p.Q2211H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LSMEM1 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 31/321 reads (10%) | called by muse, mutect2
- LTN1 | c.4061C>T p.S1354L | Missense Mutation (SNP) | VAF 52/495 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MAP3K3 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.706); called by muse, mutect2
- MYO18A | c.4815G>T p.Q1605H | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PDS5A | c.3835C>G p.Q1279E | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- POGLUT3 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2
- PRAMEF2 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 21/611 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- PTPRZ1 | c.3004G>A p.D1002N | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); called by muse, mutect2
- RAD51C | c.1112A>C p.D371A | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.01); called by muse, mutect2
- RAP1GDS1 | c.974T>A p.I325N (on ENST00000408927 / NM_001100427.2; = p.I326N on NM_021159.5) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2
- SALL2 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 18/197 reads (9%) | called by muse, mutect2, varscan2
- SIGIRR | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- SLC17A5 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2
- SLC6A1 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- SP100 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SPHK2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- SSU72P8 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TAAR9 | c.852G>C p.M284I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TAS2R39 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TBC1D19 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBX20 | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 14/486 reads (3%) | called by muse, mutect2
- TECPR1 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- TESMIN | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- TNFSF11 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TNS3 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOR2A | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 29/317 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TRPV1 | c.1765_1774del p.F589Pfs*5 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel, varscan2
- TXNRD1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2
- USP22 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2
- ZFHX2 | c.3347C>G p.S1116* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ZNF518B | c.2815C>G p.R939G | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ZNF781 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ACP2 | c.465G>A p.P155= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs763254822; called by muse, mutect2, varscan2
- ADGRF2 | c.1962C>A p.I654= (on ENST00000296862 / NM_001368115.2; = p.I586= on NM_153839.7) | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- ANO10 | c.1329C>T p.L443= | Silent (SNP) | VAF 36/337 reads (11%) | called by muse, mutect2, varscan2
- AP002512.3 | c.831C>T p.I277= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- ARHGEF17 | c.1713C>G p.L571= | Silent (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- AXIN2 | c.1080G>A p.K360= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as COSV100196479; called by muse, mutect2, varscan2
- CACNA1E | c.3753C>T p.I1251= | Silent (SNP) | VAF 34/409 reads (8%) | catalogued as COSV100701226; called by muse, mutect2
- CNOT4 | c.669C>T p.F223= | Silent (SNP) | VAF 34/616 reads (6%) | called by muse, mutect2
- CRACD | c.1308G>A p.L436= | Silent (SNP) | VAF 21/518 reads (4%) | called by muse, mutect2
- CRYBG2 | c.2529G>A p.E843= | Silent (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2
- DAP3 | c.732G>T p.L244= | Silent (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- DIS3L2 | c.846C>G p.L282= | Silent (SNP) | VAF 36/427 reads (8%) | called by muse, mutect2
- DSG3 | c.1548G>A p.L516= | Silent (SNP) | VAF 40/418 reads (10%) | catalogued as rs1025859492, COSV57124741; called by muse, mutect2
- ERBB4 | c.2235G>A p.K745= | Silent (SNP) | VAF 19/407 reads (5%) | catalogued as COSV104368600; called by muse, mutect2
- ESCO2 | c.6A>T p.A2= | Silent (SNP) | VAF 58/474 reads (12%) | called by muse, mutect2, varscan2
- FRMPD3 | c.1923G>A p.L641= | Silent (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- GJC3 | c.544C>T p.L182= | Silent (SNP) | VAF 56/584 reads (10%) | called by muse, mutect2
- GTPBP1 | c.966G>C p.L322= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- H2AW | c.210G>A p.A70= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs756445748; called by muse, mutect2
- IDI2 | c.483G>A p.L161= | Silent (SNP) | VAF 36/366 reads (10%) | catalogued as rs200190161; called by muse, mutect2
- INVS | c.507C>T p.I169= | Silent (SNP) | VAF 35/284 reads (12%) | called by muse, mutect2, varscan2
- KCNA5 | c.477G>A p.L159= | Silent (SNP) | VAF 11/251 reads (4%) | called by muse, mutect2
- KRTAP16-1 | c.936C>T p.I312= | Silent (SNP) | VAF 40/271 reads (15%) | catalogued as rs1340026797; called by muse, mutect2, varscan2
- LILRA1 | c.1329C>T p.L443= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs755467490; called by muse, mutect2
- MACF1 | c.20685G>A p.E6895= (on ENST00000372915; = p.E4940= on NM_012090.5) | Silent (SNP) | VAF 13/259 reads (5%) | called by muse, mutect2
- MAP7D3 | c.1188G>C p.V396= | Silent (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- MED13L | c.385C>T p.L129= | Silent (SNP) | VAF 39/457 reads (9%) | catalogued as COSV56132331; called by muse, mutect2
- METTL16 | c.462C>T p.L154= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2
- MPP7 | c.1713G>A p.V571= | Silent (SNP) | VAF 16/404 reads (4%) | called by muse, mutect2
- MYBPH | c.1332C>T p.P444= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- MYH1 | c.4149C>T p.A1383= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- MYO1A | c.3042C>G p.V1014= | Silent (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- MYO3A | c.3492G>C p.V1164= | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- NEUROD2 | c.1017C>A p.G339= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- NISCH | c.2124C>G p.L708= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- NTRK3 | c.159C>T p.L53= | Silent (SNP) | VAF 30/686 reads (4%) | catalogued as rs1193082361; called by muse, mutect2
- PRKAA1 | c.114C>T p.F38= | Silent (SNP) | VAF 16/412 reads (4%) | catalogued as rs1322745484, COSV57183167; called by muse, mutect2
- PSEN2 | c.408C>G p.L136= | Silent (SNP) | VAF 20/319 reads (6%) | catalogued as COSV60915428; called by muse, mutect2
- PTCH1 | c.717G>A p.A239= | Silent (SNP) | VAF 49/448 reads (11%) | catalogued as rs775723196, COSV59475778, COSV59495584; ClinVar: likely benign; called by muse, mutect2, varscan2
- REV1 | c.2148C>T p.I716= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- RGS12 | c.765C>T p.I255= | Silent (SNP) | VAF 23/362 reads (6%) | called by muse, mutect2
- SLC37A2 | c.1224C>T p.I408= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- SPDYC | c.636G>A p.S212= | Silent (SNP) | VAF 28/208 reads (13%) | catalogued as rs749800116; called by muse, mutect2, varscan2
- SRPK2 | c.969G>A p.V323= | Silent (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2, varscan2
- STAC | c.792T>C p.T264= | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- SUN1 | c.903G>T p.G301= (on ENST00000405266 / NM_001367651.1; = p.G181= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 26/427 reads (6%) | catalogued as COSV61778906; called by muse, mutect2
- SZT2 | c.6402T>G p.P2134= (on ENST00000634258 / NM_001365999.1; = p.P2077= on NM_015284.4) | Silent (SNP) | VAF 35/188 reads (19%) | called by muse, mutect2, varscan2
- TAS2R38 | c.837G>A p.V279= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as rs1180846074; called by muse, mutect2
- TMCO3 | c.1197C>T p.L399= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- TPH1 | c.369G>C p.L123= | Silent (SNP) | VAF 47/554 reads (8%) | called by muse, mutect2
- TRIM27 | c.1410C>T p.V470= | Silent (SNP) | VAF 32/312 reads (10%) | catalogued as rs762833728; called by muse, mutect2
- TRPV6 | c.1494C>T p.L498= | Silent (SNP) | VAF 20/306 reads (7%) | catalogued as rs900977918, COSV63891705; called by muse, mutect2
- TXNDC11 | c.390C>T p.L130= | Silent (SNP) | VAF 22/362 reads (6%) | catalogued as rs1270308277; called by muse, mutect2
- VLDLR | c.2433A>C p.A811= | Silent (SNP) | VAF 71/379 reads (19%) | called by muse, varscan2
- ZNF513 | c.663G>A p.L221= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV99277934; called by muse, mutect2
- ZNF81 | c.963G>C p.L321= | Silent (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- ZNF836 | c.1506A>G p.K502= | Silent (SNP) | VAF 42/315 reads (13%) | called by muse, mutect2, varscan2
- AC007998.2 | c.157-7950G>A | Intron (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- AC116351.1 | n.972C>T | RNA (SNP) | VAF 21/304 reads (7%) | called by muse, mutect2
- ANKRD26P1 | n.238A>G | RNA (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ARL13B | c.*911C>G | 3'UTR (SNP) | VAF 27/237 reads (11%) | called by muse, mutect2, varscan2
- CA4 | c.*11C>T | 3'UTR (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- CCDC66 | c.936+1040C>G | Intron (SNP) | VAF 19/258 reads (7%) | catalogued as rs1212443033; called by muse, mutect2
- CCL21 | c.*74G>C | 3'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- CLU | c.-68C>T | 5'UTR (SNP) | VAF 8/99 reads (8%) | catalogued as rs1364405894; called by muse, mutect2
- CTDSPL | c.80-35348G>A | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- EYA2 | c.-10-11367G>T | Intron (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- GPM6B | c.249-340C>G | Intron (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2, varscan2
- LINC01548 | n.211C>T | RNA (SNP) | VAF 20/204 reads (10%) | catalogued as rs538516260; called by muse, mutect2
- NAGK | chr2:71068599 G>A | 5'Flank (SNP) | VAF 13/82 reads (16%) | catalogued as rs372453300; called by muse, mutect2, varscan2
- PA2G4 | c.-145C>T | 5'UTR (SNP) | VAF 38/280 reads (14%) | called by muse, mutect2, varscan2
- RPL26P30 | n.647G>C | RNA (SNP) | VAF 45/356 reads (13%) | called by muse, mutect2, varscan2
- SDCBP2 | c.225+46C>T | Intron (SNP) | VAF 36/366 reads (10%) | catalogued as rs781096510; called by muse, mutect2
- SLC35B1 | c.*8G>T | 3'UTR (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- SUSD1 | c.2149+111C>T | Intron (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- TCP1 | c.1097+148G>A | Intron (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- TNS1 | c.-55+2668_-55+2671del | Intron (DEL) | VAF 12/98 reads (12%) | catalogued as rs1325032905; called by pindel, varscan2
- Z98752.3 | c.201+7325G>A | Intron (SNP) | VAF 22/211 reads (10%) | called by muse, mutect2, varscan2
